Somatic mutation profile of tumor specimen 0DEYDX from CCDI case PBBRJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.6 years (3,521 days).
Specimen 0DEYDX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c7d3576-9d87-46ba-8b15-29e334d4f644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEYDO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5634b90-605b-4d4c-a1ee-a14d13c85e86

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Nonsense Mutation 3, Intron 3, 3'UTR 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 31/347 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ANKRD30B | c.1773A>T p.L591F | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62812378; called by muse, mutect2
- ANKRD52 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 200/621 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as rs565915668, COSV99921560; called by muse, mutect2, varscan2
- ARAP2 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1009977209, COSV58293723; called by muse, mutect2, varscan2
- C1S | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 166/629 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV61071807; called by muse, mutect2, varscan2
- C4orf54 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 214/545 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs1331693962; called by muse, mutect2, varscan2
- CASP4 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 301/1104 reads (27%) | catalogued as rs1219592466; called by muse, mutect2, varscan2
- CCL8 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 187/481 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as rs757458292, COSV101126431; called by muse, mutect2, varscan2
- CGB1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs374210570; called by muse, mutect2, varscan2
- DNAH6 | c.3440G>A p.R1147Q | Missense Mutation (SNP) | VAF 171/690 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs766033482, COSV52868388; called by muse, mutect2, varscan2
- FBXO46 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 27/417 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1181231180; called by muse, mutect2
- FCRL5 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 205/496 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as rs373052884; called by muse, mutect2, varscan2
- GRK7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs148101386; called by muse, mutect2, varscan2
- HDAC11 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 192/436 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as COSV55474200; called by muse, mutect2, varscan2
- NAGLU | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs1347490896, COSV99864086; called by muse, mutect2, varscan2
- NDST3 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 287/664 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV56619293; called by muse, mutect2, varscan2
- NF1 | c.7010T>G p.L2337R (on ENST00000358273 / NM_001042492.3; = p.L2316R on NM_000267.3) | Missense Mutation (SNP) | VAF 285/356 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1555535179, COSV62214959, COSV62220597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKAP | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 171/349 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV65056278; called by muse, mutect2, varscan2
- NPR2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 245/597 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as CM152522, COSV61314397; called by muse, mutect2, varscan2
- ODF3 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 114/459 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.134); catalogued as COSV57295145; called by muse, mutect2, varscan2
- OTOA | c.1600C>G p.L534V (on ENST00000286149; = p.L520V on NM_144672.4) | Missense Mutation (SNP) | VAF 163/454 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1001319355, COSV99625743; called by muse, mutect2, varscan2
- PFN2 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 222/519 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1262817786, COSV99526273; called by muse, mutect2, varscan2
- PLEKHO2 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1363048166, COSV60262642; called by muse, mutect2, varscan2
- PNPLA7 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs200256242, COSV99480195; called by muse, varscan2
- RBM10 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 138/302 reads (46%) | catalogued as COSV100237770, COSV61308772, COSV61309636; called by muse, mutect2, varscan2
- RPS6KA4 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1242437574, COSV99590017; called by muse, mutect2
- SH2B2 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 155/421 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1554558168; called by muse, mutect2, varscan2
- SOX17 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 207/611 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52028103; called by muse, mutect2, varscan2
- SULT1B1 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 289/655 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371978235, COSV60206548, COSV60209064; called by muse, mutect2, varscan2
- TLN2 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 148/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs763045450, COSV100168719; called by muse, mutect2, varscan2
- TSPAN11 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201664737, COSV53821531; called by muse, mutect2, varscan2
- UGT3A2 | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 139/350 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs542105516, COSV99236587; called by muse, mutect2, varscan2
- AASDHPPT | c.248G>C p.R83P | Missense Mutation (SNP) | VAF 235/909 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- ABCB11 | c.2390G>C p.G797A | Missense Mutation (SNP) | VAF 238/805 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARVCF | c.1397-2A>G p.X466_splice | Splice Site (SNP) | VAF 84/195 reads (43%) | called by muse, mutect2, varscan2
- ATXN2 | c.1724C>T p.P575L (on ENST00000550104; = p.P415L on NM_002973.4) | Missense Mutation (SNP) | VAF 160/541 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDKL4 | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 233/880 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CHCHD3 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 67/1144 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2
- DCHS1 | c.4379C>G p.A1460G | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX18 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 239/840 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- DENND2B | c.1831del p.R611Afs*23 | Frame Shift Del (DEL) | VAF 116/368 reads (32%) | called by mutect2, varscan2
- EGFL6 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 63/742 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2
- ERCC1 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 154/485 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FKRP | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 32/531 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.358); called by muse, mutect2
- GRHL1 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 220/782 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- KCNA5 | c.1273A>C p.K425Q | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LRBA | c.6055T>C p.F2019L | Missense Mutation (SNP) | VAF 141/373 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD5 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 48/965 reads (5%) | called by muse, mutect2
- MFSD5 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYO16 | c.1867A>G p.N623D | Missense Mutation (SNP) | VAF 150/556 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSR2 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 335/1184 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS23 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 122/413 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- REPS2 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 161/460 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SCRN1 | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 226/1086 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ZNF718 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ANK3 | c.12279G>A p.R4093= (on ENST00000280772 / NM_001320874.2; = p.R614= on NM_001149.3) | Silent (SNP) | VAF 157/369 reads (43%) | called by muse, mutect2, varscan2
- FAM50B | c.159C>T p.Y53= | Silent (SNP) | VAF 98/195 reads (50%) | catalogued as COSV66655255; called by muse, mutect2, varscan2
- FBH1 | c.837C>T p.N279= (on ENST00000362091 / NM_178150.3; = p.N330= on NM_032807.4) | Silent (SNP) | VAF 254/645 reads (39%) | called by muse, mutect2, varscan2
- HSPA1A | c.12C>T p.A4= | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as rs1282823445; called by muse, mutect2, varscan2
- IRX3 | c.1101C>T p.P367= | Silent (SNP) | VAF 37/237 reads (16%) | catalogued as rs1263676732, COSV61668656; called by muse, mutect2, varscan2
- KCNA5 | c.921C>T p.P307= | Silent (SNP) | VAF 74/218 reads (34%) | called by muse, mutect2, varscan2
- PLVAP | c.33C>T p.Y11= | Silent (SNP) | VAF 88/348 reads (25%) | catalogued as rs768034061, COSV99391435; called by muse, mutect2, varscan2
- PPP1R21 | c.591G>C p.T197= | Silent (SNP) | VAF 206/768 reads (27%) | called by muse, varscan2
- RAB15 | c.594C>A p.G198= | Silent (SNP) | VAF 156/344 reads (45%) | catalogued as rs774743235, COSV99962193; called by muse, mutect2, varscan2
- SULF2 | c.2268G>A p.T756= | Silent (SNP) | VAF 188/621 reads (30%) | catalogued as rs201891400; called by muse, varscan2
- WDR74 | c.741T>G p.T247= | Silent (SNP) | VAF 161/625 reads (26%) | called by muse, mutect2, varscan2
- XKR6 | c.1794T>C p.D598= | Silent (SNP) | VAF 100/527 reads (19%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.717C>T p.R239= | Silent (SNP) | VAF 83/186 reads (45%) | catalogued as rs542045931; called by muse, mutect2, varscan2
- C6orf58 | c.*61G>A | 3'UTR (SNP) | VAF 69/163 reads (42%) | called by muse, mutect2, varscan2
- FAM9B | c.29-35T>G | Intron (SNP) | VAF 131/330 reads (40%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1899-32A>G | Intron (SNP) | VAF 81/277 reads (29%) | called by muse, mutect2, varscan2
- GRAMD1A | c.1070-57C>T | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as rs1302844169; called by muse, mutect2, varscan2
- MMP13 | c.*72G>A | 3'UTR (SNP) | VAF 63/202 reads (31%) | catalogued as rs1555016371; called by muse, mutect2, varscan2
- TMEM245 | c.*76C>T | 3'UTR (SNP) | VAF 78/175 reads (45%) | catalogued as rs1333407260; called by muse, mutect2, varscan2
